Somatic mutation profile of tumor specimen TCGA-BR-8060-01A (aliquot TCGA-BR-8060-01A-11D-2340-08) from TCGA case TCGA-BR-8060, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 75.5 years (27,561 days).
Specimen TCGA-BR-8060-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aacb3cb3-c8b7-4630-9e0c-3e07c1a02073.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8060-10A (Blood Derived Normal), aliquot TCGA-BR-8060-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f7ab52e-06e3-440e-9b0d-8226b5ca1a1c

The open-access MAF lists 238 somatic variants for this specimen: 166 protein-altering or splice-affecting, 68 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 152, Silent 68, Nonsense Mutation 4, Splice Site 3, In Frame Del 2, Intron 2, Splice Region 2, Frame Shift Del 2, 5'UTR 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.572_574del p.P191del | In Frame Del (DEL) | VAF 26/54 reads (48%) | hotspot (GDC flag); catalogued as rs1555525902; called by pindel, varscan2
- ACAN | c.4408C>T p.L1470F | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.974); catalogued as COSV100719212; called by muse, varscan2
- ADA2 | c.1508A>T p.K503M (on ENST00000262607; = p.K262M on NM_177405.3) | Missense Mutation (SNP) | VAF 158/260 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as COSV52832792, COSV99376444; called by muse, mutect2, varscan2
- ADAM29 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as rs1238683220, COSV100822233; called by muse, mutect2, varscan2
- ADGRB3 | c.3468T>A p.D1156E | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as COSV99486773; called by muse, mutect2
- ADH1A | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs781658187, COSV52925975; called by muse, mutect2, varscan2
- ADPRHL1 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.394); catalogued as COSV100733526; called by muse, mutect2, varscan2
- AGPAT5 | c.533A>G p.N178S | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.224); catalogued as COSV99576651; called by muse, mutect2, varscan2
- ALG8 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100220282; called by muse, mutect2, varscan2
- ANPEP | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100263484; called by muse, mutect2
- AQP7 | c.362T>C p.L121P | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV99953639; called by muse, mutect2, varscan2
- AQR | c.1034T>C p.F345S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV99334638; called by muse, mutect2
- ASIC2 | c.1016A>G p.H339R | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV99861072; called by muse, mutect2, varscan2
- ATXN7L2 | c.700+1G>A p.X234_splice | Splice Site (SNP) | VAF 17/74 reads (23%) | catalogued as rs1288347363, COSV63992122; called by muse, mutect2, varscan2
- BLMH | c.413T>A p.M138K | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99913223; called by muse, mutect2, varscan2
- BSN | c.1154A>C p.K385T | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs747471969, COSV99609724; called by muse, mutect2, varscan2
- BTBD3 | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 14/154 reads (9%) | catalogued as COSV99656143; called by muse, mutect2
- C9orf131 | c.890G>C p.G297A | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.23); catalogued as COSV100398299; called by muse, mutect2, varscan2
- CAMTA1 | c.263A>G p.E88G | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100352306; called by muse, mutect2, varscan2
- CATSPERG | c.2480C>T p.T827M | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as rs200588516, COSV53046116; called by muse, mutect2, varscan2
- CCNB3 | c.3839C>A p.T1280N | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99329815; called by muse, mutect2, varscan2
- CCT8L2 | c.1378G>C p.V460L | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.216); catalogued as rs747634629, COSV100743103; called by muse, mutect2, varscan2
- CDK14 | c.1015C>G p.Q339E (on ENST00000380050 / NM_001287135.2; = p.Q321E on NM_012395.3) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.894); catalogued as COSV99726807; called by muse, mutect2, varscan2
- CDON | c.198A>C p.K66N | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as COSV99701957; called by muse, mutect2, varscan2
- CEACAM18 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV101140695; called by muse, mutect2, varscan2
- CENPE | c.4945T>A p.L1649M | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as COSV54381064, COSV99479056; called by muse, mutect2, varscan2
- CHST9 | c.1091A>G p.Y364C | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568088591, COSV99410896; called by muse, mutect2, varscan2
- CLEC4D | c.123G>A p.V41= | Splice Region (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100223149; called by muse, mutect2
- CNTNAP1 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.152); catalogued as COSV99226128, COSV99226969; called by muse, mutect2, varscan2
- COL5A1 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs375600865, COSV65664570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CP | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV99224445; called by muse, mutect2
- CSF2RB | c.2230T>G p.L744V | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1476009791, COSV99454411; called by muse, varscan2
- CSGALNACT1 | c.634+2T>C p.X212_splice | Splice Site (SNP) | VAF 30/81 reads (37%) | catalogued as COSV100175556; called by muse, mutect2, varscan2
- CTTN | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 119/191 reads (62%) | catalogued as COSV57236176; called by muse, mutect2, varscan2
- CUEDC2 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs372005158, COSV50041722, COSV99193899; called by muse, mutect2, varscan2
- DCP2 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66616242; called by muse, mutect2, varscan2
- DDX18 | c.1166A>C p.D389A | Missense Mutation (SNP) | VAF 58/232 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV99604780; called by muse, mutect2, varscan2
- DIP2A | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770506169, COSV100596316; called by muse, mutect2, varscan2
- DMKN | c.198A>C p.K66N | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100303942; called by muse, mutect2, varscan2
- DNAH17 | c.9754T>A p.Y3252N | Missense Mutation (SNP) | VAF 205/449 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101103399; called by muse, mutect2, varscan2
- DNAH5 | c.11696T>G p.L3899R | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99453930; called by muse, mutect2, varscan2
- DSCAM | c.3267T>G p.S1089R | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV68020610; called by muse, mutect2
- EFHB | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV99860199; called by muse, mutect2, varscan2
- EIF5 | c.1112T>G p.I371S | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99385001; called by muse, mutect2, varscan2
- ESYT1 | c.688T>G p.C230G | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57272473, COSV99920270; called by muse, mutect2, varscan2
- EXD3 | c.1945G>A p.G649S | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367737146; called by muse, mutect2, varscan2
- FAM13C | c.1708A>G p.R570G | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99514547; called by muse, mutect2, varscan2
- FAT3 | c.5465A>G p.K1822R | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV53075739, COSV99970735; called by muse, mutect2, varscan2
- FCN2 | c.216A>G p.G72= | Splice Region (SNP) | VAF 30/98 reads (31%) | catalogued as COSV99391436; called by muse, mutect2, varscan2
- FCRLB | c.184T>C p.Y62H | Missense Mutation (SNP) | VAF 57/298 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100396367; called by muse, mutect2, varscan2
- FEM1C | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99174423; called by muse, mutect2, varscan2
- FOLH1 | c.1486A>G p.S496G | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV57050333, COSV99923892; called by muse, mutect2, varscan2
- FREM1 | c.6009G>T p.Q2003H | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV101085419; called by muse, mutect2, varscan2
- GPATCH2 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754073389, COSV65127424; called by muse, mutect2, varscan2
- GPR156 | c.1145A>C p.K382T | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100251704; called by muse, mutect2, varscan2
- GPR160 | c.361T>A p.C121S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.069); catalogued as COSV100576178; called by muse, mutect2, varscan2
- GPR160 | c.812C>A p.A271E | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV100576180; called by muse, mutect2, varscan2
- GTF2IRD1 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99735463; called by muse, mutect2, varscan2
- H4C7 | c.205T>C p.Y69H | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV55100016; called by muse, mutect2, varscan2
- HLTF | c.2060C>G p.A687G | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.11); catalogued as COSV100027116; called by muse, mutect2, varscan2
- IFI16 | c.1223A>T p.Q408L | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV99858145; called by muse, mutect2, varscan2
- IL1RAPL1 | c.363-1G>A p.X121_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100150238; called by muse, mutect2, varscan2
- INHA | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199544141; called by muse, mutect2, varscan2
- INHBA | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV99638338; called by muse, mutect2, varscan2
- IQGAP1 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV99185338; called by muse, mutect2, varscan2
- IRX6 | c.452A>C p.K151T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51860883, COSV99306793; called by muse, mutect2, varscan2
- IZUMO1R | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as COSV100126930; called by muse, mutect2, varscan2
- JAG2 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 140/218 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs1368959697, COSV100078802, COSV59311063; called by muse, mutect2, varscan2
- JAGN1 | c.126C>G p.Y42* | Nonsense Mutation (SNP) | VAF 26/100 reads (26%) | catalogued as COSV100314816; called by muse, mutect2, varscan2
- KIAA1109 | c.10799C>A p.A3600D | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99175004; called by mutect2, varscan2
- KIAA1755 | c.359T>C p.M120T | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99642659; called by muse, mutect2, varscan2
- KLF13 | c.652T>C p.Y218H | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV100207234; called by muse, mutect2, varscan2
- KRT40 | c.697T>G p.L233V | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV100898904; called by muse, mutect2
- LELP1 | c.65A>C p.K22T | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.215); catalogued as COSV100907358; called by muse, mutect2
- LYST | c.2566A>G p.T856A | Missense Mutation (SNP) | VAF 186/238 reads (78%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.001); catalogued as COSV101090256; called by muse, mutect2, varscan2
- MAK | c.1574T>C p.L525P | Missense Mutation (SNP) | VAF 71/288 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100504672; called by muse, mutect2, varscan2
- MATN1 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs141354318; called by muse, mutect2, varscan2
- MIS18BP1 | c.341T>A p.I114K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100173244; called by muse, mutect2, varscan2
- MS4A14 | c.283T>C p.Y95H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.916); catalogued as rs780301996, COSV100280726; called by muse, mutect2, varscan2
- MTMR14 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV99931555; called by muse, mutect2, varscan2
- MUC16 | c.5424A>C p.K1808N | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as COSV101201503; called by muse, mutect2, varscan2
- MUC17 | c.7634C>T p.P2545L | Missense Mutation (SNP) | VAF 277/597 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100074964; called by muse, mutect2, varscan2
- MUC6 | c.6397C>T p.P2133S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV101424783; called by muse, mutect2, varscan2
- MYNN | c.374C>A p.S125Y | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV100582334; called by muse, mutect2, varscan2
- NAP1L3 | c.1063A>C p.S355R | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV59074880; called by muse, mutect2, varscan2
- NCKAP5 | c.3044T>C p.V1015A | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV100493931, COSV58442274; called by muse, mutect2, varscan2
- NCKAP5 | c.2418G>T p.R806S | Missense Mutation (SNP) | VAF 157/323 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV100494296; called by muse, mutect2, varscan2
- NDUFAF7 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as rs897236169, COSV99135779; called by muse, mutect2, varscan2
- NOX5 | c.2177A>C p.K726T | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV99534730; called by muse, mutect2, varscan2
- OBSCN | c.11152G>C p.E3718Q | Missense Mutation (SNP) | VAF 37/357 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.045); catalogued as COSV99484020; called by muse, mutect2, varscan2
- OPTN | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.852); catalogued as rs182957382; called by muse, mutect2, varscan2
- OR5V1 | c.769T>G p.F257V | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV101011460; called by muse, mutect2, varscan2
- PAIP1 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as rs748118672, COSV100166751; called by muse, mutect2, varscan2
- PAX8 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs868015719, CM065372, COSV99640080; called by muse, mutect2, varscan2
- PCDH10 | c.1007A>T p.N336I | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.771); catalogued as COSV99994453; called by muse, mutect2, varscan2
- PCDHA3 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 75/336 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.801); catalogued as rs577444100, COSV100793406; called by muse, mutect2, varscan2
- PCDHGA12 | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52744421; called by muse, mutect2, varscan2
- PCDHGB1 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as COSV99546380; called by muse, mutect2, varscan2
- PDE6B | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV55329905, COSV99728351; called by muse, mutect2, varscan2
- PI4KB | c.1108C>G p.P370A (on ENST00000368873 / NM_001369623.1; = p.P382A on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV99650137; called by muse, mutect2, varscan2
- PKN2 | c.1060G>T p.V354F | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.34); catalogued as rs1253742289, COSV100281745; called by muse, mutect2, varscan2
- PLPPR3 | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 81/111 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100609072; called by muse, mutect2, varscan2
- PNPLA8 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV57553551; called by muse, mutect2, varscan2
- POLR1G | c.917C>A p.T306K | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.139); catalogued as COSV99185395; called by muse, mutect2
- PSG7 | c.830G>A p.G277D | Missense Mutation (SNP) | VAF 68/442 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as rs191124850, COSV101343335; called by muse, mutect2, varscan2
- PSTPIP2 | c.977T>G p.V326G | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV101297382; called by muse, mutect2, varscan2
- PTPRM | c.3397C>T p.R1133W | Missense Mutation (SNP) | VAF 129/250 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772640308, COSV100160216; called by muse, mutect2, varscan2
- PTPRO | c.1403T>A p.V468E | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV99841687; called by muse, mutect2, varscan2
- QARS1 | c.875A>C p.K292T | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100070257; called by muse, mutect2, varscan2
- RDH16 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as COSV100660074, COSV100660170; called by muse, mutect2, varscan2
- RGL3 | c.1181T>C p.F394S | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100805321; called by muse, mutect2, varscan2
- RIMS1 | c.4780A>G p.R1594G | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53462674, COSV53463828; called by muse, mutect2, varscan2
- RIMS2 | c.2194T>G p.S732A (on ENST00000666250 / NM_001348490.2; = p.S540A on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs1296611006, COSV99198434; called by muse, mutect2, varscan2
- RPTN | c.2266A>G p.R756G | Missense Mutation (SNP) | VAF 102/695 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100285754; called by muse, mutect2, varscan2
- RRM2 | c.850C>G p.P284A | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.403); catalogued as COSV100459830, COSV58817178; called by muse, mutect2, varscan2
- SCP2D1 | c.195A>C p.K65N | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99602205; called by muse, mutect2, varscan2
- SDHA | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs1352756438, COSV99372160; called by muse, mutect2, varscan2
- SEMG1 | c.190T>C p.S64P | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs369245912; called by muse, mutect2
- SERPINA10 | c.905T>C p.L302P | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100004026; called by muse, mutect2, varscan2
- SH2D2A | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 65/530 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100949161, COSV100949179; called by muse, mutect2, varscan2
- SLC17A4 | c.1249T>G p.F417V | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as COSV100930671; called by muse, mutect2, varscan2
- SLC24A2 | c.160T>G p.F54V | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.08); catalogued as COSV99647415; called by muse, mutect2
- SLCO2B1 | c.1050C>A p.N350K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.149); catalogued as COSV99215199; called by muse, varscan2
- SP140 | c.597G>C p.Q199H | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as COSV100614058; called by muse, mutect2, varscan2
- SP140 | c.854A>T p.K285M | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as COSV100614059; called by muse, mutect2, varscan2
- SPAG17 | c.6366A>C p.K2122N | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100310483; called by muse, mutect2, varscan2
- SPECC1L | c.2240G>T p.R747L | Missense Mutation (SNP) | VAF 61/276 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100063209, COSV104405026; called by muse, mutect2, varscan2
- SRD5A2 | c.59T>G p.L20R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as CM086534, COSV99252604; called by muse, mutect2, varscan2
- SRPK2 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.075); catalogued as rs772745182, COSV61960454; called by muse, mutect2, varscan2
- SYNPO2 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.686); catalogued as COSV100206358; called by muse, mutect2, varscan2
- SYT9 | c.604T>G p.L202V | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100609112; called by muse, mutect2, varscan2
- TAF4 | c.2641A>G p.R881G | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99435000; called by muse, mutect2, varscan2
- TANC1 | c.2278G>A p.V760M | Missense Mutation (SNP) | VAF 100/370 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as rs375321124; called by muse, mutect2, varscan2
- TBX19 | c.1003A>G p.S335G | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100892411; called by muse, mutect2, varscan2
- TCTA | c.185A>C p.N62T | Missense Mutation (SNP) | VAF 147/471 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV99648603, COSV99648765; called by muse, mutect2, varscan2
- TELO2 | c.146G>A p.R49K | Missense Mutation (SNP) | VAF 81/388 reads (21%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV99248698; called by muse, mutect2, varscan2
- TENM2 | c.5014A>T p.T1672S (on ENST00000518659 / NM_001122679.2; = p.T1433S on NM_001080428.3) | Missense Mutation (SNP) | VAF 30/267 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV101319396; called by muse, mutect2, varscan2
- TEX15 | c.6020T>C p.L2007P (on ENST00000256246; = p.L2390P on NM_001350162.2) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99822096; called by muse, mutect2, varscan2
- TIMD4 | c.1082T>G p.V361G | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99192880; called by muse, mutect2, varscan2
- TLN2 | c.3049G>C p.A1017P | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as COSV100169981; called by muse, mutect2, varscan2
- TMED5 | c.313A>G p.M105V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.296); catalogued as COSV100939210; called by muse, mutect2, varscan2
- TMEM132E | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV100396759; called by muse, mutect2, varscan2
- TMEM79 | c.287A>T p.D96V | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99828111; called by muse, mutect2, varscan2
- TOPBP1 | c.3128A>G p.N1043S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1375821186, COSV99605806; called by muse, mutect2, varscan2
- TRIO | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.972); catalogued as COSV100710934; called by muse, mutect2
- TRRAP | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV62841979, COSV62842077; called by muse, mutect2, varscan2
- TSC22D3 | c.248T>A p.L83Q | Missense Mutation (SNP) | VAF 181/264 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100226985; called by muse, mutect2, varscan2
- TTI1 | c.2825A>G p.D942G | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100989747; called by muse, mutect2, varscan2
- TTN | c.3312A>C p.Q1104H (on ENST00000591111; = p.Q1058H on NM_003319.4) | Missense Mutation (SNP) | VAF 32/141 reads (23%) | PolyPhen possibly damaging (0.808); catalogued as COSV100592269, COSV59896378, COSV60101462; called by muse, mutect2, varscan2
- UBE3B | c.1526A>C p.K509T | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs765426919, COSV99784444; called by muse, mutect2, varscan2
- URB2 | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 76/505 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99271870; called by muse, mutect2, varscan2
- USH2A | c.7679A>C p.N2560T | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100242230; called by muse, mutect2, varscan2
- VWA3B | c.1477C>G p.L493V | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101346163, COSV68245648; called by muse, mutect2, varscan2
- VWA5A | c.304G>C p.G102R | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100795745; called by muse, mutect2, varscan2
- WDR45 | c.359A>G p.K120R (on ENST00000376372 / NM_001029896.2; = p.K121R on NM_007075.3) | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100540375; called by muse, mutect2, varscan2
- XDH | c.191A>G p.K64R | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.083); catalogued as COSV101052461; called by muse, mutect2, varscan2
- ZNF184 | c.1661G>A p.G554E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV99280052; called by muse, mutect2, varscan2
- ZNF25 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.069); catalogued as COSV100224770; called by muse, mutect2, varscan2
- ZNF341 | c.2134C>T p.R712C (on ENST00000375200 / NM_001282935.1; = p.R705C on NM_032819.4) | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1344790766, COSV100678046; called by muse, mutect2, varscan2
- ZNF439 | c.490A>T p.K164* | Nonsense Mutation (SNP) | VAF 8/158 reads (5%) | catalogued as COSV100397576; called by muse, mutect2
- ZNF667 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99410942; called by muse, mutect2, varscan2
- ZNF701 | c.360G>A p.M120I (on ENST00000301093; = p.M54I on NM_018260.3) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as COSV99990986; called by muse, mutect2
- FAM161B | c.1782del p.E594Dfs*9 (on ENST00000651776; = p.E531Dfs*9 on NM_152445.3) | Frame Shift Del (DEL) | VAF 57/103 reads (55%) | called by mutect2, pindel*, varscan2*
- GMPPB | c.713_730del p.Q238_R243del | In Frame Del (DEL) | VAF 75/314 reads (24%) | called by mutect2, pindel, varscan2
- MED1 | c.2498del p.N833Ifs*31 | Frame Shift Del (DEL) | VAF 45/184 reads (24%) | called by mutect2, pindel, varscan2
- MUC5B | c.7661dup p.T2555Dfs*126 | Frame Shift Ins (INS) | VAF 65/318 reads (20%) | called by mutect2, pindel, varscan2
- ADAMTS18 | c.1563T>C p.C521= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as rs1471265132, COSV99274086; called by muse, mutect2, varscan2
- AFF1 | c.3447A>G p.T1149= | Silent (SNP) | VAF 75/325 reads (23%) | catalogued as rs1307610920, COSV100321038; called by muse, mutect2, varscan2
- ALG8 | c.1092A>C p.R364= | Silent (SNP) | VAF 20/157 reads (13%) | catalogued as COSV100220279, COSV55203354; called by muse, mutect2, varscan2
- ANK2 | c.765G>A p.R255= | Silent (SNP) | VAF 29/148 reads (20%) | catalogued as COSV100004091, COSV52157098, COSV52171040; called by muse, mutect2, varscan2
- ARSD | c.1584C>A p.P528= | Silent (SNP) | VAF 26/38 reads (68%) | catalogued as COSV101144751; called by muse, mutect2, varscan2
- ASNSD1 | c.762G>A p.E254= | Silent (SNP) | VAF 23/134 reads (17%) | catalogued as COSV99641364; called by muse, mutect2, varscan2
- ATF1 | c.246C>T p.D82= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs549207784, COSV100016225; called by muse, mutect2
- BCL9 | c.714C>A p.P238= | Silent (SNP) | VAF 39/476 reads (8%) | catalogued as COSV99325785; called by muse, mutect2
- CCDC121 | c.33T>C p.A11= | Silent (SNP) | VAF 28/163 reads (17%) | catalogued as COSV99270496; called by muse, mutect2, varscan2
- CCDC78 | c.462C>T p.P154= | Silent (SNP) | VAF 87/175 reads (50%) | catalogued as rs199585619, COSV99285170; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDC42BPA | c.2364T>A p.T788= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as COSV100506806, COSV100506997; called by muse, mutect2, varscan2
- CHD6 | c.601A>C p.R201= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV100498686; called by muse, mutect2, varscan2
- CHRNA2 | c.1470G>A p.K490= | Silent (SNP) | VAF 56/239 reads (23%) | catalogued as COSV99532491; called by muse, mutect2, varscan2
- COL5A1 | c.3795T>G p.A1265= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100880560; called by muse, mutect2, varscan2
- CPB1 | c.1032C>G p.T344= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as COSV99294509; called by muse, mutect2
- CSF2RB | c.2268A>G p.P756= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV99454414; called by muse, varscan2
- CTC1 | c.1917T>C p.S639= | Silent (SNP) | VAF 75/251 reads (30%) | catalogued as rs770110056, COSV100236770; called by muse, mutect2, varscan2
- DMD | c.5544G>A p.K1848= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100822571, COSV100823989; called by muse, mutect2, varscan2
- EPYC | c.213T>C p.T71= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV99664907; called by muse, mutect2, varscan2
- GDA | c.760T>C p.L254= | Silent (SNP) | VAF 39/614 reads (6%) | catalogued as COSV52992212, COSV99429796; called by muse, mutect2
- GNAI2 | c.183C>T p.Y61= | Silent (SNP) | VAF 50/116 reads (43%) | catalogued as COSV99807250; called by muse, mutect2, varscan2
- HIVEP2 | c.90A>G p.Q30= | Silent (SNP) | VAF 103/282 reads (37%) | catalogued as rs755232431, COSV99175355; called by muse, mutect2, varscan2
- IFTAP | c.285A>G p.E95= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100531380; called by muse, mutect2, varscan2
- KIR2DL3 | c.558T>C p.P186= | Silent (SNP) | VAF 21/268 reads (8%) | called by muse, mutect2
- KRTAP9-4 | c.165T>G p.T55= | Silent (SNP) | VAF 115/243 reads (47%) | catalogued as COSV100484962; called by muse, mutect2, varscan2
- LAMB3 | c.1507C>A p.R503= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100620520; called by muse, mutect2, varscan2
- MED1 | c.3684T>C p.G1228= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as COSV100328147; called by muse, varscan2
- MUC16 | c.17202T>G p.S5734= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV101201501; called by muse, mutect2, varscan2
- MUC16 | c.6576T>G p.V2192= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV101201502; called by muse, mutect2, varscan2
- MYH4 | c.816G>A p.E272= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV99702181; called by muse, mutect2, varscan2
- NCAPD2 | c.3051C>A p.L1017= | Silent (SNP) | VAF 160/216 reads (74%) | catalogued as COSV100217434; called by muse, mutect2, varscan2
- NCOR1 | c.4123C>A p.R1375= | Silent (SNP) | VAF 35/145 reads (24%) | catalogued as COSV99251941; called by muse, mutect2, varscan2
- NME8 | c.85T>C p.L29= | Silent (SNP) | VAF 47/159 reads (30%) | catalogued as COSV99553833; called by muse, mutect2, varscan2
- OR13C4 | c.957A>G p.*319= | Silent (SNP) | VAF 58/127 reads (46%) | catalogued as COSV52928069, COSV99470294; called by muse, mutect2, varscan2
- OR2T33 | c.69A>G p.Q23= | Silent (SNP) | VAF 48/237 reads (20%) | catalogued as COSV100532277, COSV58814377; called by muse, varscan2
- ORAI2 | c.132G>A p.S44= | Silent (SNP) | VAF 34/168 reads (20%) | catalogued as rs1198790353, COSV100709974; called by muse, mutect2, varscan2
- P2RY10 | c.582G>A p.A194= | Silent (SNP) | VAF 37/57 reads (65%) | catalogued as COSV50680499; called by muse, mutect2, varscan2
- PCDHB1 | c.1203T>G p.S401= | Silent (SNP) | VAF 30/142 reads (21%) | catalogued as rs782699473, COSV100128391; called by muse, mutect2, varscan2
- PCDHGB6 | c.1188T>G p.S396= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV99546382; called by muse, mutect2, varscan2
- PGGHG | c.1908C>T p.F636= | Silent (SNP) | VAF 27/267 reads (10%) | catalogued as rs1321019646, COSV101164679; called by muse, mutect2, varscan2
- PHRF1 | c.4893C>T p.R1631= (on ENST00000264555 / NM_001286581.2; = p.R1630= on NM_020901.4) | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs780745082, COSV99213397; called by muse, mutect2, varscan2
- PITRM1 | c.2283C>A p.I761= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV99829578; called by muse, mutect2
- PKHD1 | c.10647A>G p.G3549= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100945332; called by muse, mutect2, varscan2
- PLD6 | c.582C>T p.Y194= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as rs142631639; called by muse, mutect2, varscan2
- PON3 | c.945G>A p.R315= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as COSV99672711; called by muse, mutect2, varscan2
- PSG7 | c.831T>A p.G277= | Silent (SNP) | VAF 69/444 reads (16%) | catalogued as COSV101343334; called by muse, mutect2, varscan2
- RAB3A | c.132C>T p.D44= | Silent (SNP) | VAF 162/255 reads (64%) | catalogued as rs1194158560, COSV99718117; called by muse, mutect2, varscan2
- RAB9A | c.54T>G p.V18= | Silent (SNP) | VAF 38/164 reads (23%) | catalogued as COSV99689768; called by muse, mutect2, varscan2
- RAD51B | c.411T>G p.A137= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV101185400; called by muse, mutect2
- RASGRF1 | c.3117C>G p.A1039= | Silent (SNP) | VAF 28/162 reads (17%) | catalogued as rs141077574, COSV101174482; called by muse, mutect2, varscan2
- RCBTB2 | c.67T>C p.L23= | Silent (SNP) | VAF 116/154 reads (75%) | catalogued as COSV100749645; called by muse, mutect2, varscan2
- SAFB2 | c.2760C>T p.G920= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as rs747451273, COSV53044202, COSV99386079; called by muse, mutect2, varscan2
- SLC11A1 | c.21C>A p.P7= | Silent (SNP) | VAF 26/230 reads (11%) | catalogued as COSV99262432; called by muse, mutect2, varscan2
- SMARCC2 | c.2839C>A p.R947= | Silent (SNP) | VAF 40/160 reads (25%) | catalogued as COSV53237410, COSV99519638; called by muse, mutect2, varscan2
- SORCS1 | c.2787C>T p.N929= | Silent (SNP) | VAF 48/151 reads (32%) | catalogued as rs199658375, COSV99550086; called by muse, mutect2, varscan2
- SP3 | c.1020T>C p.P340= | Silent (SNP) | VAF 32/143 reads (22%) | catalogued as COSV100022215; called by muse, mutect2, varscan2
- TAB3 | c.1701G>A p.A567= | Silent (SNP) | VAF 42/70 reads (60%) | catalogued as rs771530217, COSV99915550; called by muse, mutect2, varscan2
- TNFAIP1 | c.297A>G p.Q99= | Silent (SNP) | VAF 10/188 reads (5%) | catalogued as COSV99880445; called by muse, mutect2
- TRIB2 | c.945G>A p.S315= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs369596172; called by muse, mutect2, varscan2
- TRIB3 | c.462C>A p.I154= | Silent (SNP) | VAF 9/107 reads (8%) | catalogued as COSV99423998; called by muse, mutect2
- UGT3A1 | c.1038G>A p.V346= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV57096608, COSV57103219; called by muse, mutect2
- UMODL1 | c.3933C>T p.F1311= (on ENST00000408910 / NM_001004416.2; = p.F1439= on NM_173568.3) | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as COSV101252707; called by muse, mutect2, varscan2
- UNC5D | c.2604C>T p.P868= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV99778559; called by muse, mutect2, varscan2
- WDR6 | c.1407C>T p.A469= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs151099969; called by muse, mutect2, varscan2
- ZNF184 | c.1662A>G p.G554= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99280049; called by mutect2, varscan2
- ZNF208 | c.876A>G p.K292= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV101237197; called by muse, mutect2, varscan2
- ZNF208 | c.12G>A p.L4= | Silent (SNP) | VAF 7/152 reads (5%) | catalogued as rs1448149974, COSV101237198; called by muse, mutect2
- ZNF534 | c.117G>A p.E39= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV99989937, COSV99990157; called by muse, mutect2, varscan2
- FBXL7 | c.740-1216C>T | Intron (SNP) | VAF 21/211 reads (10%) | catalogued as rs753206885, COSV100310463, COSV100310775; called by muse, mutect2
- RPS3 | c.539-167_539-165del | Intron (DEL) | VAF 78/130 reads (60%) | called by mutect2, pindel, varscan2
- SNORD114-19 | n.35T>G | RNA (SNP) | VAF 27/109 reads (25%) | called by muse, mutect2, varscan2
- ZNF680 | c.-2A>G | 5'UTR (SNP) | VAF 22/146 reads (15%) | catalogued as COSV100549327; called by muse, mutect2, varscan2
